Somatic mutation profile of tumor specimen MP2PRT-PAUSTG-TMP1-A (aliquot MP2PRT-PAUSTG-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAUSTG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (981 days).
Specimen MP2PRT-PAUSTG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f9074cd-2fa6-49c2-807d-7559e623064a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUSTG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUSTG-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82427adb-9c56-4825-9326-62642df45069

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4459C>T p.H1487Y | Missense Mutation (SNP) | VAF 186/498 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1057519207, COSV52115420, COSV52137541; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 26/441 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CLMN | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 157/560 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.075); catalogued as rs767751056; called by muse, mutect2, varscan2
- UGT2A3 | c.864G>T p.K288N | Missense Mutation (SNP) | VAF 87/350 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs372283656; called by muse, mutect2, varscan2
- CER1 | c.143A>T p.E48V | Missense Mutation (SNP) | VAF 160/656 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.184); called by muse, mutect2
- FARSB | c.1171T>C p.F391L | Missense Mutation (SNP) | VAF 57/231 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GJA1 | c.998A>T p.Q333L | Missense Mutation (SNP) | VAF 192/671 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- PATL1 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 81/233 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- PKHD1L1 | c.7310T>A p.F2437Y | Missense Mutation (SNP) | VAF 86/367 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ZFR2 | c.998C>A p.A333D | Missense Mutation (SNP) | VAF 238/623 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CPEB1 | c.1533C>T p.N511= (on ENST00000617958; = p.N446= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 213/553 reads (39%) | catalogued as rs752859272, COSV55620945; called by muse, mutect2, varscan2
- CRYGB | c.72C>A p.P24= | Silent (SNP) | VAF 156/420 reads (37%) | catalogued as CD1211658; called by muse, mutect2, varscan2
- NDST3 | c.1167C>A p.L389= | Silent (SNP) | VAF 123/534 reads (23%) | called by muse, mutect2, varscan2
